Somatic mutation profile of tumor specimen MP2PRT-PAVWBY-TMP1-A (aliquot MP2PRT-PAVWBY-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVWBY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,499 days).
Specimen MP2PRT-PAVWBY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eef25ee6-3431-43d3-9ead-46545587903b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWBY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWBY-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7331db9-cd59-4b58-bfb9-9e58e5bf923c

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B4 | c.3541G>C p.V1181L | Missense Mutation (SNP) | VAF 137/347 reads (39%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV52714055; called by muse, mutect2, varscan2
- ERF | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 244/594 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as rs752101971; called by muse, mutect2, varscan2
- RTN4RL1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 205/492 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1407040461; called by muse, mutect2, varscan2
- ZC3H11B | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 134/693 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.336); catalogued as rs1264220597; called by muse, mutect2
- AFF1 | c.871A>G p.T291A | Missense Mutation (SNP) | VAF 29/420 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDRT15L2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 103/217 reads (47%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MBOAT7 | c.1297A>G p.I433V | Missense Mutation (SNP) | VAF 322/771 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRF | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 135/371 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 ins AAGGCC | 3'Flank (INS) | VAF 22/141 reads (16%) | called by mutect2, pindel, varscan2
- IGLV4-60 | chr22:22162681 ins TGTCC | 3'Flank (INS) | VAF 27/81 reads (33%) | called by mutect2, pindel, varscan2
